FM case AD2105 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Primary site: Bronchus and lung.
https://portal.gdc.cancer.gov/cases/31e0039a-b74b-4a2c-b147-4902e5336492

Male, 24.0 years: diagnosis not reported by GDC of the lung; specimen biopsied or resected from the lung. Sample type: Tumor.
